Gene-level copy-number profile of tumor specimen C3L-09379-02 from CPTAC case C3L-09379, project CPTAC-3 (Stomach — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Stomach, NOS; AJCC pathologic stage: Stage IIA; Tumor grade: G2; Age at diagnosis: 64.2 years (23,463 days).
Specimen C3L-09379-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Stomach; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file d1f53bad-92d7-4ea9-ad95-bf3bc3d8fee3.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3L-09379-31 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,708 have no estimate.
https://portal.gdc.cancer.gov/files/b8e5e78c-0851-4715-b30d-e500fcbdd01d

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 2: 2,164; copy number 3: 551; copy number 4: 36,054; copy number 5: 19,651; copy number 6: 332; copy number 7: 43; copy number 8: 14; copy number 9: 47; copy number 10: 38; copy number 14: 10; copy number 15: 11.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 77 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr11:77,659,996–77,821,017, 1 gene, copy number 9 (within-gene range 7–9): RSF1.
- chr11:77,717,712–78,582,156, 32 genes, copy number 9–10: RSF1-IT2, FTH1P16, RSF1-IT1, AP000580.1, AAMDC, AP002812.2, AP002812.3, AP002812.5, AP002812.1, INTS4, AP002812.4, AP003032.2, KCTD14, NDUFC2-KCTD14, AP003032.1, THRSP, NDUFC2, ALG8, RNU6-126P, KCTD21-AS1, KCTD21, USP35, GAB2, AP002985.1, AP003086.1, AP003086.3, AP003086.2, LINC02728, NARS2, AP003110.1, RNU6-311P, COPS8P3.
- chr17:39,980,807–39,997,959, 1 gene, copy number 9: PSMD3.
- chr17:40,287,879–40,836,270, 33 genes, copy number 9: CDC6, RARA, AC080112.4, RARA-AS1, AC080112.3, GJD3, AC080112.1, PPIAP54, RNA5SP441, AC080112.2, TOP2A, Y_RNA, RPL23AP75, IGFBP4, AC018629.1, TNS4, AC004585.1, CCR7, AC004585.2, SMARCE1, AC073508.2, AC073508.3, KRT222, AC073508.1, KRT24, KRT223P, KRT25, KRT26, KRT27, KRT28, AC090283.1, KRT10, TMEM99.
- chr17:41,712,331–41,851,447, 10 genes, copy number 14: GAST, HAP1, RNA5SP442, RN7SL399P, JUP, P3H4, FKBP10, NT5C3B, KLHL10, AC125257.1.

Autosomal genes at a single copy (total copy number 1): 0. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
